Somatic mutation profile of tumor specimen BA2993D (aliquot aq-BA2993D) from BEATAML1.0 case 2210, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,430 days).
Specimen BA2993D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 989846bd-3b69-45d2-b669-98731f0289d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2274D (Solid Tissue Normal), aliquot aq-BA2274D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b847e9-2b45-4de4-b7d8-a94dbcd37305

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'Flank 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs754861621, COSV50746909; called by mutect2, varscan2
- MST1R | c.3883G>T p.D1295Y | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56567924, COSV99619528; called by muse, mutect2
- ROBO1 | c.4156G>A p.G1386R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV71393667; called by muse, mutect2, varscan2
- SMR3B | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV59229436; called by muse, mutect2, varscan2
- ZFHX4 | c.2547C>A p.F849L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1250836707, COSV99268292; called by muse, mutect2, varscan2
- C1QL2 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FCHO1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GAB4 | c.135G>T p.W45C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- TTC17 | c.1808T>C p.I603T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JAKMIP3 | c.1296G>A p.K432= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs1448956470; called by muse, mutect2, varscan2
- MYL3 | chr3:46833609 C>T | 3'Flank (SNP) | VAF 77/171 reads (45%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1965236 G>T | 3'Flank (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
